Somatic mutation profile of tumor specimen TCGA-DU-8158-01A (aliquot TCGA-DU-8158-01A-11D-2253-08) from TCGA case TCGA-DU-8158, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 57.8 years (21,129 days).
Specimen TCGA-DU-8158-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7a6ffb93-78e7-4034-a13e-7f33bd50b60e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DU-8158-10A (Blood Derived Normal), aliquot TCGA-DU-8158-10A-01D-2253-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c3b56c98-ec4c-4e62-8e3d-b08248f02871

The open-access MAF lists 38 somatic variants for this specimen: 31 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 29, Silent 7, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.741dup p.P248Tfs*5 | Frame Shift Ins (INS) | VAF 37/94 reads (39%) | catalogued as rs587782341, CI043805, COSV64288762; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ALDH4A1 | c.538C>G p.L180V | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.291); catalogued as COSV51890115; called by muse, varscan2
- APBA1 | c.611C>A p.A204E | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.062); catalogued as COSV55221633; called by muse, mutect2, varscan2
- APOO | c.13A>T p.I5F | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.125); catalogued as COSV64870120; called by muse, mutect2, varscan2
- ATG16L2 | c.247G>C p.V83L | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as COSV58361136, COSV58362584; called by muse, varscan2
- BCL9L | c.1876A>G p.M626V | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV52681903; called by muse, mutect2, varscan2
- BRINP3 | c.1957G>A p.D653N | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV66513581; called by muse, mutect2, varscan2
- CACNA1D | c.5557G>C p.E1853Q (on ENST00000350061 / NM_001128840.3; = p.E1873Q on NM_000720.4) | Missense Mutation (SNP) | VAF 97/299 reads (32%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.519); catalogued as COSV55437466, COSV55452415; called by muse, mutect2, varscan2
- COPS2 | c.5C>G p.S2C | Missense Mutation (SNP) | VAF 47/97 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.7); catalogued as COSV54644193; called by muse, mutect2, varscan2
- DCAF12L1 | c.140C>T p.T47M | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.288); catalogued as rs747904012, COSV64421176; called by muse, mutect2, varscan2
- DHX38 | c.863C>T p.P288L | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs148934675, COSV51699807; called by muse, mutect2, varscan2
- DNAH11 | c.3157C>T p.L1053F | Missense Mutation (SNP) | VAF 64/233 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1287536955, COSV60939877, COSV60941522, COSV60964341; called by muse, mutect2, varscan2
- DNAH7 | c.878G>A p.R293H | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.912); catalogued as rs372305897; called by muse, mutect2, varscan2
- EGFR | c.251A>T p.E84V | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51771223; called by muse, mutect2, varscan2
- EZHIP | c.625G>A p.A209T | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as COSV57958030; called by muse, mutect2, varscan2
- GABRA1 | c.1138G>C p.A380P | Missense Mutation (SNP) | VAF 42/179 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0.038); catalogued as COSV50098467, COSV50098851; called by muse, mutect2, varscan2
- KIF19 | c.961G>A p.A321T | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as rs761159685, COSV63428809; called by muse, mutect2
- KIF1B | c.2744C>T p.T915M (on ENST00000377086 / NM_001365952.1; = p.T869M on NM_015074.3) | Missense Mutation (SNP) | VAF 21/301 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.042); catalogued as rs749523745, COSV55803403; called by muse, mutect2
- LRP1B | c.8129G>C p.G2710A | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.949); catalogued as COSV101254324, COSV67186611; called by muse, mutect2, varscan2
- LUZP4 | c.841G>A p.V281M | Missense Mutation (SNP) | VAF 23/141 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs201126715, COSV64218411; called by muse, mutect2, varscan2
- PDE8A | c.299G>A p.C100Y | Missense Mutation (SNP) | VAF 43/80 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59634823, COSV59638589; called by muse, mutect2, varscan2
- PLCG2 | c.2201C>A p.P734H | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63867470; called by muse, mutect2, varscan2
- PSMC6 | c.173A>G p.E58G (on ENST00000612399; = p.E44G on NM_002806.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71628525; called by muse, mutect2, varscan2
- RNF19A | c.826C>T p.R276C | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as rs1172163595, COSV61992358; called by muse, mutect2, varscan2
- SEMA3E | c.155C>A p.P52H | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.95); PolyPhen benign (0.006); catalogued as COSV57079752; called by muse, mutect2, varscan2
- SLITRK3 | c.1906C>A p.P636T | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as COSV53845618; called by muse, mutect2, varscan2
- TMEM39B | c.506C>T p.T169M | Missense Mutation (SNP) | VAF 19/203 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.824); catalogued as rs372163088; called by muse, mutect2
- WNK1 | c.4412C>T p.P1471L (on ENST00000315939 / NM_018979.4; = p.P1224L on NM_014823.3) | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs902748213, COSV60025554; called by muse, mutect2, varscan2
- ZFHX3 | c.361G>T p.D121Y | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.949); catalogued as COSV51708589; called by muse, mutect2, varscan2
- ZXDB | c.1750G>A p.A584T | Missense Mutation (SNP) | VAF 14/282 reads (5%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.989); catalogued as COSV66492321; called by muse, mutect2
- BACH1 | c.1367_1368del p.L456* | Frame Shift Del (DEL) | VAF 24/78 reads (31%) | called by mutect2, pindel, varscan2
- ALDH4A1 | c.573C>T p.S191= | Silent (SNP) | VAF 20/106 reads (19%) | catalogued as COSV51890101; called by muse, varscan2
- ARMC3 | c.1707C>T p.N569= | Silent (SNP) | VAF 54/119 reads (45%) | catalogued as rs370847654, COSV53062445; called by muse, mutect2, varscan2
- BCR | c.2628C>G p.S876= | Silent (SNP) | VAF 22/55 reads (40%) | catalogued as COSV59926464; called by muse, mutect2, varscan2
- HLTF | c.435T>G p.P145= | Silent (SNP) | VAF 37/61 reads (61%) | catalogued as COSV59498816; called by muse, mutect2, varscan2
- HSPA13 | c.681C>T p.G227= | Silent (SNP) | VAF 36/145 reads (25%) | catalogued as rs1480329529, COSV53464543; called by muse, mutect2, varscan2
- METTL16 | c.957C>T p.S319= | Silent (SNP) | VAF 98/319 reads (31%) | catalogued as rs1230202968, COSV54012011; called by muse, mutect2, varscan2
- PBRM1 | c.4080C>T p.P1360= | Silent (SNP) | VAF 6/94 reads (6%) | catalogued as COSV56261217; called by muse, mutect2
